TARGET case TARGET-52-PAVDPR — Rhabdoid Tumor (TARGET-RT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/ee33dcef-f61c-5ee0-9c65-a4eb475a2406

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 2 years.

Diagnoses (1)
1. Malignant rhabdoid tumor: ICD-O-3 morphology code: 8963/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 2.1 years (749 days); Year of diagnosis: 2012; Pediatric kidney staging: Tumor biopsied only at diagnosis, distant metastasis identified at diagnosis.
   Treatment given: Protocol identifier: AREN03B2.

Follow-up (2 entries)
- Year of follow up: 2012; Timepoint: Last Contact.
- Follow-up contact recording only the day: follow-up.

Biospecimens (1 sample)
- Sample TARGET-52-PAVDPR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_RT_ClinicalData_Discovery_and_Validation_Supplement_20230322.xlsx, for sample TARGET-52-PAVDPR-01A-01D:
- Cohort: Validation
- Stage of the primary tumour at the time of diagnosis: 4

Additional fields from the TARGET clinical supplement workbook TARGET_RT_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Stage: IIIB/IV
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: RT
